Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5678, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5678-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL:

RENAL CELL CARCINOMA (8.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE (90% CLEAR CELLS, 10% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, CONFINED TO THE KIDNEY. (SEE COMMENT)

Renal cortical cyst.

Margins of resection free of tumor.

METASTATIC RENAL CELL CARCINOMA (1.3 CM MAXIMUM DIMENSION) IN ADRENAL GLAND.

One lymph node, no tumor present.

COMMENT

Renal cell carcinoma in the left kidney is confined to the kidney and does not invade into the renal sinus adipose tissue, perinephric adipose tissue, or the renal vein. The tumor pushes against the renal sinus adipose tissue and the perinephric adipose tissue, however there is no invasion of these tissues.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL - A left radical nephrectomy specimen (25.0 x 12.0 x 10.0 cm) with kidney (15.0 x 8.0 x 6.0 cm), with segments of renal vein (2.0 cm in length x 1.0 cm in diameter), and ureter and adrenal gland 4.0 x 3.0 x 1.0 cm.

There is a nodular hemorrhagic yellow mass (8.0 x 7.0 x 7.0 x cm) located in the medial mid to upper portion of the kidney. The center of the tumor is necrotic. The majority of the tumor bulges into the renal sinus and perinephric adipose tissue, with a small portion of the tumor attached to the medial aspect of the renal parenchyma,. The tumor focally abuts the external aspect of the renal vein. However, there is no definite renal vein invasion. The tumor is 0.4 cm from the adrenal gland, but there is no direct invasion of the adrenal gland. The tumor abuts the Gerota's fascia margin in multiple areas.

There is also a smooth wall cyst (4.0 x 4.0 x 4.0 cm) in the kidney, which is filled with clear fluid.

There is a solid yellow and white tumor nodule (1.3 x 1.0 x 1.0 cm) in the adrenal gland.

Tumor is submitted for the vaccine protocol.

INK CODE: Black-Gerota's fascia margin.

SECTION CODE: A1, vascular margin; A2, tumor adjacent to renal vein; A3, tumor adjacent to renal sinus; A4, tumor adjacent to kidney and renal sinus; A5, tumor adjacent to renal vein; A6, tumor in fat adjacent to Gerota's fascia margin; A7, representative section of tumor; A8, tumor adjacent to Gerota's fascia margin; A7, representative section of tumor; A8, tumor adjacent to Gerota's fascia margin; A9, tumor adjacent to renal sinus; A10, tumor adjacent to Gerota's fascia margin and adrenal gland; A11, A12 adrenal nodule, entirely submitted; A13, renal cyst; A14, representative section of non-neoplastic kidney.

Source: NCI Genomic Data Commons file bc13c5ea-787c-4e38-bcb1-e453b036918e (TCGA-CJ-5678.76F4B3F9-CF9C-439D-B1F1-B3B1E355ABF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).